Somatic mutation profile of tumor specimen 0DTVG8 from CCDI case PBCHUJ, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Rhabdoid tumor, NOS; Tissue or organ of origin: Lower limb, NOS; Age at diagnosis: 1.9 years (705 days).
Specimen 0DTVG8: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) cf73aeda-1c57-43e1-be7f-7dfb571cc6d4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DTVGB (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d6d21e0f-e580-4637-83cd-8f4ea44dfdbf

The open-access MAF lists 9 somatic variants for this specimen: 4 protein-altering or splice-affecting, 2 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 4, Silent 2, Intron 2, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FBXL18 | c.154G>A p.V52I | Missense Mutation (SNP) | VAF 144/985 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs773760680, COSV66668898; called by muse, mutect2, varscan2
- HMCN1 | c.2450A>G p.Q817R | Missense Mutation (SNP) | VAF 323/2074 reads (16%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.759); catalogued as COSV54931341; called by muse, mutect2, varscan2
- LRRC8A | c.874G>A p.D292N | Missense Mutation (SNP) | VAF 96/756 reads (13%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as rs756269981; called by muse, varscan2
- PAK3 | c.1676G>A p.R559H (on ENST00000262836 / NM_001324328.2; = p.R544H on NM_002578.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 57/992 reads (6%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.976); catalogued as rs1251435916, COSV53276325, COSV99457053; called by muse, mutect2
- ADAMTS1 | c.1722G>C p.T574= | Silent (SNP) | VAF 250/1593 reads (16%) | called by muse, mutect2, varscan2
- SLCO1B1 | c.657T>A p.G219= | Silent (SNP) | VAF 63/2100 reads (3%) | called by muse, mutect2
- EXOC8 | c.-48C>T | 5'UTR (SNP) | VAF 35/254 reads (14%) | catalogued as rs1219887207; called by muse, mutect2, varscan2
- ME2 | c.393-86T>A | Intron (SNP) | VAF 12/135 reads (9%) | called by muse, mutect2, varscan2
- PCID2 | c.37-95A>C | Intron (SNP) | VAF 7/96 reads (7%) | catalogued as COSV55814242; called by muse, mutect2
